Somatic mutation profile of tumor specimen TCGA-61-2002-01A (aliquot TCGA-61-2002-01A-01W-0722-08) from TCGA case TCGA-61-2002, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.9 years (17,115 days).
Specimen TCGA-61-2002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1518b24-e57c-4d40-a8b1-55ff0b48283c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2002-11A (Solid Tissue Normal), aliquot TCGA-61-2002-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b810f8f-8c3f-4db2-8fa2-90dd108fbb2a

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.893T>A p.M298K | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV55295866; called by muse, mutect2, varscan2
- ADAP2 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); catalogued as COSV58296290; called by muse, mutect2, varscan2
- CASZ1 | c.2659C>G p.P887A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as COSV59739474; called by muse, mutect2, varscan2
- CLNS1A | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs372932790; called by muse, mutect2, varscan2
- CRHBP | c.711C>G p.C237W | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99169515, COSV99169527; called by muse, mutect2
- CTAGE1 | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 157/467 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as COSV66944196; called by muse, mutect2, varscan2
- DNAH3 | c.9794C>T p.S3265F | Missense Mutation (SNP) | VAF 122/473 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032548515, COSV54540551; called by muse, mutect2, varscan2
- EPAS1 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1366088332, COSV55389063; called by muse, mutect2, varscan2
- IL18R1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52124974, COSV52126346; called by muse, mutect2, varscan2
- LPGAT1 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV65352224; called by muse, mutect2, varscan2
- MAGEF1 | c.200T>A p.L67* | Nonsense Mutation (SNP) | VAF 67/117 reads (57%) | catalogued as COSV58634214; called by muse, mutect2, varscan2
- NAMPT | c.715G>C p.G239R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99748176; called by muse, varscan2
- NCKAP5 | c.3327G>T p.E1109D | Missense Mutation (SNP) | VAF 131/517 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV58464401; called by muse, mutect2, varscan2
- NECTIN4 | c.552C>A p.D184E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as COSV63513600; called by muse, mutect2, varscan2
- NRG1 | c.1780C>G p.P594A (on ENST00000405005 / NM_013964.5; = p.P599A on NM_013956.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV55170457, COSV99829563; called by muse, mutect2, varscan2
- OSBPL8 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53887316; called by muse, mutect2, varscan2
- PKNOX2 | c.39G>C p.M13I | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV53551544; called by muse, mutect2, varscan2
- PLA2G4F | c.923G>C p.S308T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.318); catalogued as COSV51828625; called by muse, mutect2, varscan2
- SEMA6C | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV59006295; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 101/187 reads (54%) | PolyPhen benign (0.082); catalogued as COSV60328585; called by muse, mutect2, varscan2
- STXBP5L | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 216/457 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs747930759, COSV56527029; called by muse, mutect2, varscan2
- TCF7L2 | c.841C>A p.P281T (on ENST00000355995 / NM_001367943.1; = p.P258T on NM_030756.5) | Missense Mutation (SNP) | VAF 153/678 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV53344553, COSV53346102, COSV99525609; called by muse, mutect2, varscan2
- TICRR | c.4453G>C p.V1485L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV51545191; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRPM2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1254363541, COSV55974198; called by muse, mutect2, varscan2
- TTN | c.86752A>T p.T28918S (on ENST00000591111; = p.T21494S on NM_003319.4) | Missense Mutation (SNP) | VAF 98/384 reads (26%) | PolyPhen possibly damaging (0.461); catalogued as COSV60243288; called by muse, varscan2
- UBE3D | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 97/333 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as COSV52756145; called by muse, mutect2, varscan2
- WDR93 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 30/147 reads (20%) | catalogued as COSV51534237; called by muse, mutect2, varscan2
- WNK3 | c.4723C>T p.Q1575* | Nonsense Mutation (SNP) | VAF 59/129 reads (46%) | catalogued as COSV100670691, COSV63615321; called by muse, mutect2, varscan2
- ZNF16 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52763490; called by muse, varscan2
- ZNF16 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV52765011, COSV99429901; called by muse, varscan2
- ALS2 | c.282T>G p.I94M | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2
- ANXA7 | c.360_370+6del p.X120_splice | Splice Site (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- GPR179 | c.840C>G p.I280M (on ENST00000621958; = p.I279M on NM_001004334.4) | Missense Mutation (SNP) | VAF 95/156 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB6 | c.779_783delinsC p.V260Afs*27 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | called by pindel, varscan2*
- ANKFY1 | c.79C>T p.L27= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV58920575; called by muse, mutect2, varscan2
- GRAMD1C | c.735A>G p.E245= | Silent (SNP) | VAF 104/206 reads (50%) | catalogued as COSV63983781; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2034G>A p.V678= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV63100680; called by muse, mutect2, varscan2
- KDM8 | c.204C>T p.S68= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs372258213; called by muse, mutect2, varscan2
- MUC17 | c.9417T>A p.S3139= | Silent (SNP) | VAF 118/437 reads (27%) | catalogued as COSV60298492; called by muse, mutect2, varscan2
- NEXMIF | c.3222G>A p.P1074= | Silent (SNP) | VAF 195/480 reads (41%) | catalogued as rs748567167, COSV50037885; ClinVar: likely benign; called by muse, mutect2, varscan2
- P3H2 | c.450C>G p.P150= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1168299160, COSV60025868; called by muse, mutect2, varscan2
- PSMD11 | c.408G>A p.L136= | Silent (SNP) | VAF 72/168 reads (43%) | catalogued as COSV55580377; called by muse, mutect2, varscan2
- SIKE1 | c.375A>G p.E125= | Silent (SNP) | VAF 112/372 reads (30%) | catalogued as COSV99285366; called by muse, mutect2, varscan2
- GP6 | c.*398G>A | 3'UTR (SNP) | VAF 47/82 reads (57%) | catalogued as COSV59978947; called by muse, mutect2, varscan2
